Gene-level copy-number profile of tumor specimen ALCH-B1PK-TTP1-A from ALCHEMIST case ALCH-B1PK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.3 years (24,223 days).
Specimen ALCH-B1PK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f86d0dd4-e1de-4b87-a141-67cd7b3e780b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1PK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/67c52393-d16b-4cbd-b3d8-b1a1e10fa083

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 8,102; copy number 2: 45,393; copy number 3: 3,996; copy number 4: 1,065; copy number 5: 319; copy number 6: 19; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:115,147,605–115,564,389, 2 genes: AC026341.1, EIF4E2P2.
- chr3:149,999,645–150,000,690, 1 gene (within-gene range 0–1): HNRNPA1P24.
- chr9:119,935,053–119,937,832, 1 gene: LINC01613.
- chr16:20,451,461–20,489,659, 2 genes: ACSM2A, AC137056.2.
- chr17:6,853,861–6,954,107, 1 gene (within-gene range 0–2): ALOX12P2.
- chr17:6,927,472–6,928,191, 1 gene (within-gene range 0–2): AC027763.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 340 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:186,296,279–186,375,693, 3 genes, copy number 5: PRG4, TPR, RNU6-1240P.
- chr14:27,258,717–38,371,338, 184 genes, copy number 5–7 (broad region; genes not listed).
- chr22:19,130,279–19,144,684, 1 gene, copy number 5 (within-gene range 2–5): ESS2.
- chr22:19,146,993–21,867,680, 152 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,637. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
